Surgical pathology report (de-identified scan), TCGA case TCGA-ZS-A9CF, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Tayside Tissue Bank, specimen TCGA-ZS-A9CF-02A (Recurrent Tumor).

[page 1 of 4]
Supplementary Report

Nature of Specimen(s)

1. Left lobe liver
2. Portal lymph node - 1

MALE

Clinical Information Supplied

Left hepatectomy today. Past medical history of primary hepatocellular carcinoma segment 5&6 resected lesion Haemochromatosis.

Macro Report

PROCUREMENT DATE:

1. Received is a left lobe of liver measuring 132x95x58mm. The surgical resection margin is inked blue. On transverse slicing 2 distinct tumour nodules each with a hard or cream-white cut surface are noted. Focal areas of necrosis and softening are present. The larger lesion measures 72x59x45mm and the smaller 60x35x44mm. The larger lesion is 4mm from the inked blue resection margin. The smaller lesion is clear by approximately 26mm. An area of firm white scarring is present at the resection margin. This is especially clear near the larger lesion.

2. A fragment of brown-white tissue 21x8x8mm. On transverse slicing a lymph node is revealed.

Micro Report

1. Sections confirm two tumours with morphological features consistent with hepatocellular carcinoma. Both tumours show an anastomosing trabecular architecture with large atypical cells bearing abundant cytoplasm and focally producing bile. The larger lesion is associated with spread into small branches of portal veins. Although the lesion approaches close to the inked resection margin the final resection margin is entirely clear of tumour. The smaller of the 2 lesions, as noted macroscopically, is well clear of the resection margin. Adjacent liver parenchyma shows some chronic inflammation in portal areas and steatosis. Both are mild in degree. There is no obvious evidence of iron pigment on routine staining however liver histochemistry will be performed and results issued in a supplementary report.

ICD O 3

Page 1 of 4

Carcinoma, Hepatocellular NOS
8170/3

Site: Liver C22.0

2015/19/14

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

[page 2 of 4]
Date Recvd

Date Issued

Supplementary Report

Conclusion

Two nodules of hepatocellular carcinoma. Both completely excised.

2. Sections show a reactive lymph node with numerous
oleogranuloma. There is no evidence of malignancy.

Signature of Pathologist(s)

Page 2 of 4

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

[page 3 of 4]
Date Recvd

Date Issued

Supplementary Report

Results of histochemical stains of normal liver. No evidence of excess iron. No evidence of fibrosis, cirrhosis or collapse. No evidence of Orcein positive granules. No evidence of PAS positive diastase resistant globules.

Signature of Pathologist(s)

Page 3 of 4

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

[page 4 of 4]
Date Recvd

Date Issued

Supplementary Report

Tumour cells show canalicular staining pattern with polyclonal CEA and focally CD10. There is weak expression of HepR1. The findings are in keeping with hepatocellular carcinoma.

Signature of Pathologist(s)

Page 4 of 4

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR
	Recurrence - primary also received.

Source: NCI Genomic Data Commons file 1f7d0bee-36c2-4092-9099-645f392a1b27 (TCGA-ZS-A9CF.5D79D370-F174-4CCB-AF64-5617EBF352BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).